Somatic mutation profile of tumor specimen TCGA-AR-A1AY-01A (aliquot TCGA-AR-A1AY-01A-21D-A12Q-09) from TCGA case TCGA-AR-A1AY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 65.5 years (23,927 days).
Specimen TCGA-AR-A1AY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40c43ddd-23bd-45e7-a5a5-af4bc67bd882.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AY-10A (Blood Derived Normal), aliquot TCGA-AR-A1AY-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0c22b96-b351-43f3-bcf4-8af8d5f1e42d

The open-access MAF lists 57 somatic variants for this specimen: 44 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 39, Silent 13, Nonsense Mutation 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADAC | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV51760956; called by muse, mutect2, varscan2
- ABCD3 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 163/397 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV64644185; called by muse, mutect2, varscan2
- AFP | c.1747T>A p.C583S | Missense Mutation (SNP) | VAF 77/124 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56926648; called by muse, mutect2, varscan2
- ARHGAP39 | c.3005C>T p.A1002V (on ENST00000276826 / NM_001308208.2; = p.A1033V on NM_025251.2) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.087); catalogued as rs1258787378, COSV99432760; called by muse, mutect2
- ARSF | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 217/354 reads (61%) | SIFT tolerated (0.56); PolyPhen benign (0.206); catalogued as rs778537453, COSV63839197; called by muse, mutect2, varscan2
- B3GALT5 | c.124G>C p.G42R | Missense Mutation (SNP) | VAF 154/377 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV58198090; called by muse, mutect2, varscan2
- BRPF3 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 107/481 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60209208; called by muse, mutect2, varscan2
- BSN | c.5024C>A p.T1675N | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV56525354; called by muse, mutect2
- CARD10 | c.2038C>T p.P680S | Missense Mutation (SNP) | VAF 106/141 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV52657351; called by muse, mutect2, varscan2
- CBLC | c.1387C>G p.P463A | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV54325173; called by muse, mutect2, varscan2
- CYLD | c.1787G>A p.G596D | Missense Mutation (SNP) | VAF 82/126 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM074130, COSV61096907; called by muse, mutect2, varscan2
- CYSLTR2 | c.411C>A p.F137L | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV99935299; called by muse, mutect2
- EEFSEC | c.819C>A p.F273L | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54621782, COSV54631275; called by muse, mutect2, varscan2
- FEZF2 | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 135/358 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51864233, COSV99334542; called by muse, mutect2, varscan2
- FHOD3 | c.1842G>T p.R614S (on ENST00000359247 / NM_001281739.3; = p.R631S on NM_025135.5) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.957); catalogued as COSV57184447; called by muse, mutect2, varscan2
- KCNE2 | c.140A>T p.Y47F | Missense Mutation (SNP) | VAF 155/402 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.28); catalogued as COSV51710751; called by muse, mutect2, varscan2
- KCNN3 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99678739; called by muse, mutect2
- LAMA3 | c.4793G>A p.R1598H | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs762184728, COSV52541066; called by muse, mutect2, varscan2
- LELP1 | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 113/205 reads (55%) | PolyPhen probably damaging (0.944); catalogued as rs767013309, COSV64202694; called by muse, mutect2, varscan2
- NAA50 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 106/607 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs777291080, COSV53786919; called by muse, mutect2, varscan2
- NUAK1 | c.623T>G p.F208C | Missense Mutation (SNP) | VAF 92/224 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV54607097; called by muse, mutect2, varscan2
- OSBP2 | c.2242G>A p.G748S | Missense Mutation (SNP) | VAF 145/181 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367777319; called by muse, mutect2, varscan2
- PEF1 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV65484173; called by muse, mutect2, varscan2
- PLCB4 | c.3155A>G p.K1052R | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV53813910; called by muse, mutect2
- PTPN14 | c.2683G>T p.E895* | Nonsense Mutation (SNP) | VAF 14/350 reads (4%) | catalogued as COSV100872779; called by muse, mutect2
- REG1B | c.363C>A p.Y121* | Nonsense Mutation (SNP) | VAF 93/260 reads (36%) | catalogued as COSV59307373; called by muse, mutect2, varscan2
- RNF10 | c.1132C>T p.R378W | Missense Mutation (SNP) | VAF 16/560 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1358752595, COSV100378787; called by muse, mutect2
- SERINC2 | c.487G>A p.G163S (on ENST00000373709 / NM_178865.5; = p.G167S on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/394 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs201000290, COSV65490723, COSV65491462; called by muse, mutect2, varscan2
- STYXL2 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV54808923; called by muse, mutect2, varscan2
- TBC1D32 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 80/208 reads (38%) | catalogued as rs1488064917, COSV51551577; called by muse, mutect2, varscan2
- TECTA | c.4382C>G p.P1461R | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50776668; called by muse, mutect2
- TOMM40L | c.716C>G p.T239R | Missense Mutation (SNP) | VAF 109/478 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.326); catalogued as COSV63469108; called by muse, mutect2, varscan2
- TOR1AIP2 | c.648G>T p.W216C | Missense Mutation (SNP) | VAF 645/1523 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV62626937; called by muse, mutect2, varscan2
- TRPC6 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60259316; called by muse, mutect2, varscan2
- UBN2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV56029245, COSV56034539; called by muse, mutect2, varscan2
- VCL | c.1378C>T p.R460* | Nonsense Mutation (SNP) | VAF 33/66 reads (50%) | catalogued as rs1335966343, COSV53013455; called by muse, mutect2, varscan2
- VIT | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as COSV64898705; called by muse, mutect2, varscan2
- YLPM1 | c.2973T>G p.H991Q | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV53118593; called by muse, mutect2, varscan2
- ZNF157 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 138/197 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV65659610; called by muse, mutect2, varscan2
- ZNF654 | c.1756C>T p.L586F | Missense Mutation (SNP) | VAF 127/387 reads (33%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as rs758133144, COSV58807019; called by muse, mutect2, varscan2
- ZNF683 | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV62874521, COSV62875432; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.396C>G p.I132M | Missense Mutation (SNP) | VAF 20/756 reads (3%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.891); catalogued as COSV100008450, COSV58350028; called by muse, mutect2
- AFF1 | c.3017_3018del p.E1006Vfs*2 | Frame Shift Del (DEL) | VAF 154/392 reads (39%) | called by pindel, varscan2
- GOLGA6L9 | c.1059G>T p.K353N | Missense Mutation (SNP) | VAF 151/246 reads (61%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- ATP2B1 | c.807C>T p.G269= | Silent (SNP) | VAF 78/240 reads (33%) | catalogued as COSV53811754; called by muse, mutect2, varscan2
- DRAM1 | c.708T>C p.G236= | Silent (SNP) | VAF 97/316 reads (31%) | catalogued as COSV51599780; called by muse, mutect2, varscan2
- MYLK | c.639C>T p.N213= | Silent (SNP) | VAF 145/374 reads (39%) | catalogued as rs146073242; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA8 | c.1461C>T p.N487= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs1349278415, COSV65325330; called by muse, mutect2, varscan2
- PTPRO | c.1296G>T p.L432= | Silent (SNP) | VAF 70/159 reads (44%) | catalogued as COSV55519903; called by muse, mutect2, varscan2
- RBM22 | c.357G>A p.Q119= | Silent (SNP) | VAF 85/128 reads (66%) | catalogued as COSV52272810; called by muse, mutect2, varscan2
- SEMA3F | c.261C>T p.R87= | Silent (SNP) | VAF 60/309 reads (19%) | catalogued as rs771554773, COSV50029379; called by muse, mutect2, varscan2
- SGCZ | c.609C>A p.S203= | Silent (SNP) | VAF 168/323 reads (52%) | catalogued as COSV101166523, COSV66037031; called by muse, mutect2, varscan2
- STKLD1 | c.1260G>A p.L420= | Silent (SNP) | VAF 66/109 reads (61%) | catalogued as COSV64242158; called by muse, mutect2, varscan2
- SYNCRIP | c.84G>A p.Q28= | Silent (SNP) | VAF 132/369 reads (36%) | catalogued as COSV62289060; called by muse, mutect2, varscan2
- TLL1 | c.1794G>A p.Q598= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as rs1265647974, COSV50313366, COSV50327864; called by muse, mutect2
- TRUB1 | c.966T>C p.P322= | Silent (SNP) | VAF 11/148 reads (7%) | catalogued as COSV100076141; called by muse, mutect2
- TSGA10IP | c.1077C>T p.A359= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as COSV73245397; called by muse, mutect2, varscan2
